Somatic mutation profile of tumor specimen TARGET-30-PASTKC-01A (aliquot TARGET-30-PASTKC-01A-01D) from TARGET case TARGET-30-PASTKC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 8.3 years (3,035 days).
Specimen TARGET-30-PASTKC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec9c14d9-4dc9-4a2c-8e09-fe697c1823cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASTKC-10A (Blood Derived Normal), aliquot TARGET-30-PASTKC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac820bbe-f7ac-4bd9-a19d-9fd01c7b62ed

The open-access MAF lists 102 somatic variants for this specimen: 80 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 62, Silent 22, Nonsense Mutation 11, Splice Site 2, Frame Shift Del 2, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC006059.2 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59606103; called by muse, mutect2, varscan2
- AKAP13 | c.6541G>T p.V2181L (on ENST00000394518 / NM_007200.5; = p.V2185L on NM_006738.6) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV63451227, COSV63467554; called by muse, mutect2, varscan2
- ARHGAP20 | c.352A>T p.K118* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV52808019; called by muse, varscan2
- ARMC6 | c.1024G>A p.E342K (on ENST00000392336; = p.E317K on NM_033415.4) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV54180265; called by muse, mutect2, varscan2
- ARNT | c.485A>C p.Q162P | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV62230018; called by muse, mutect2, varscan2
- ASH2L | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV51698798; called by muse, mutect2, varscan2
- BAAT | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as COSV52287678; called by muse, mutect2, varscan2
- BBOX1 | c.732T>A p.N244K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54189676; called by muse, mutect2
- BLNK | c.282C>A p.D94E | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56409548; called by muse, mutect2, varscan2
- C1orf105 | c.502C>G p.R168G | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs778326712, COSV62958958; called by muse, mutect2, varscan2
- CACNA1A | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs369084322; called by muse, mutect2, varscan2
- CD1D | c.608-1G>A p.X203_splice | Splice Site (SNP) | VAF 36/100 reads (36%) | catalogued as COSV63808590; called by muse, mutect2, varscan2
- CELSR1 | c.1544T>G p.I515S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV53085484; called by muse, mutect2, varscan2
- CIPC | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 34/71 reads (48%) | catalogued as rs1201798596, COSV62376774; called by muse, mutect2, varscan2
- CLHC1 | c.1454A>G p.N485S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV68463734; called by muse, mutect2, varscan2
- CNNM1 | c.1975C>G p.H659D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV63200855; called by muse, mutect2, varscan2
- COL14A1 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52849359; called by muse, mutect2, varscan2
- COL5A3 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs773466006, COSV53407588; called by muse, mutect2, varscan2
- DHX9 | c.1451C>A p.A484D | Missense Mutation (SNP) | VAF 111/205 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62358660; called by muse, mutect2, varscan2
- DPP8 | c.2564A>T p.Y855F (on ENST00000341861 / NM_001320875.2; = p.Y739F on NM_017743.6) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55676817; called by muse, mutect2, varscan2
- DUXA | c.38C>A p.T13K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV73729543; called by muse, mutect2, varscan2
- ECPAS | c.3361C>A p.L1121I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52193277; called by muse, mutect2, varscan2
- EPN2 | c.1617C>A p.F539L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59060328; called by muse, mutect2, varscan2
- FAM120A | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.991); catalogued as COSV52902590; called by muse, mutect2, varscan2
- FAM47C | c.2619C>A p.D873E | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.29); PolyPhen benign (0.09); catalogued as COSV63724643; called by muse, mutect2, varscan2
- FGD6 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.057); catalogued as COSV59691193; called by muse, mutect2, varscan2
- FGD6 | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV59691205; called by muse, mutect2, varscan2
- FZD10 | c.743C>G p.T248S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472539; called by muse, mutect2, varscan2
- HCRTR2 | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV63794419; called by muse, mutect2, varscan2
- HOXC11 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs1418742082, COSV54532487; called by muse, mutect2, varscan2
- IGFALS | c.1139A>C p.Q380P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV51905022; called by muse, varscan2
- IPO5 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV55161086; called by muse, mutect2, varscan2
- KANSL3 | c.1019A>G p.H340R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.142); catalogued as COSV62616104; called by muse, mutect2, varscan2
- KCNA1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66836428; called by muse, mutect2, varscan2
- KCNN4 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53454841; called by muse, mutect2, varscan2
- KRTAP20-1 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | PolyPhen probably damaging (0.993); catalogued as COSV58167934; called by muse, mutect2, varscan2
- LCN12 | c.288A>G p.I96M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.215); catalogued as COSV65421600; called by muse, mutect2, varscan2
- LNX1 | c.1449G>A p.W483* (on ENST00000263925 / NM_001126328.3; = p.W387* on NM_032622.2) | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV55783136; called by muse, mutect2, varscan2
- LRP1B | c.10082G>T p.R3361L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV67196916, COSV67285422; called by muse, mutect2, varscan2
- MASP1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs115647447, COSV51459178; called by muse, mutect2, varscan2
- MATR3 | c.1829C>A p.S610Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as CM161384, COSV63076252; called by muse, mutect2, varscan2
- MPP3 | c.144+1G>A p.X48_splice | Splice Site (SNP) | VAF 14/132 reads (11%) | catalogued as COSV68197709; called by muse, mutect2, varscan2
- MUC17 | c.6053C>T p.T2018I | Missense Mutation (SNP) | VAF 99/338 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV60282723; called by muse, mutect2, varscan2
- MYBPC1 | c.557G>T p.G186V (on ENST00000550270 / NM_206820.2; = p.G211V on NM_002465.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750326778, COSV62251621; called by muse, mutect2
- NKTR | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 28/45 reads (62%) | catalogued as COSV51770248; called by muse, mutect2, varscan2
- NOL6 | c.2228G>A p.G743D | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53039921; called by muse, mutect2, varscan2
- NR2C1 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as COSV58009020; called by muse, mutect2, varscan2
- PAPOLB | c.1328G>C p.G443A | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV68199817; called by muse, mutect2, varscan2
- PBRM1 | c.1797del p.Y600Ifs*42 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | catalogued as COSV56265934; called by mutect2, pindel, varscan2
- PFAS | c.3751G>A p.A1251T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV58979020, COSV58983191; called by muse, mutect2, varscan2
- PGBD2 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 31/165 reads (19%) | catalogued as rs376861979; called by muse, varscan2
- PIGR | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.914); catalogued as COSV62903459; called by muse, mutect2
- PPP1R3A | c.1634T>C p.M545T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52878472; called by muse, mutect2, varscan2
- PRRC2A | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV63224387; called by muse, mutect2, varscan2
- RNF43 | c.2177G>T p.W726L | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV68457335; called by muse, mutect2, varscan2
- SAMD9L | c.1523C>G p.T508R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV59080287; called by muse, mutect2, varscan2
- SLC6A13 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs781142259, COSV58255103; called by muse, mutect2, varscan2
- SRBD1 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55396836; called by muse, mutect2, varscan2
- SSH3 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 25/114 reads (22%) | catalogued as COSV57383732; called by muse, mutect2, varscan2
- TCN1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV57252533; called by muse, mutect2, varscan2
- TRIO | c.582T>G p.D194E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV60079428; called by muse, mutect2, varscan2
- TRMT10C | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV59305287; called by muse, mutect2, varscan2
- TRPV4 | c.1335C>G p.N445K | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV55680934; called by muse, mutect2, varscan2
- VIT | c.1636G>C p.E546Q (on ENST00000389975 / NM_001177969.1; = p.E561Q on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199704976, COSV64895637; called by muse, mutect2, varscan2
- WDR70 | c.1030G>T p.G344* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV54269055; called by muse, mutect2, varscan2
- ZDHHC18 | c.786C>G p.R262= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as rs753598475, COSV65145177, COSV65145268; called by muse, mutect2, varscan2
- ZEB2 | c.3228C>A p.H1076Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57953125; called by muse, mutect2, varscan2
- ZFHX3 | c.9011C>A p.S3004Y | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV51711814; called by muse, mutect2, varscan2
- ZRANB1 | c.1561T>G p.L521V | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61470252; called by muse, mutect2, varscan2
- CCT3 | c.222T>A p.H74Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CCT3 | c.221A>T p.H74L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GNPAT | c.1993_1996del p.M665Lfs*7 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- ILVBL | c.1658_1675del p.Q553_V559delinsL | In Frame Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- IPO5 | c.413A>T p.D138V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIR2DL4 | c.808C>A p.P270T (on ENST00000396284; = p.P231T on NM_001080770.2) | Missense Mutation (SNP) | VAF 108/338 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, varscan2
- OR5AR1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH11Y | c.1955C>A p.S652* (on ENST00000400457 / NM_032973.2; = p.S641* on NM_032971.3) | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- PSMA5 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 15/359 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- PURG | c.507_521delinsATG p.S169_D174delinsRC | In Frame Del (DEL) | VAF 19/71 reads (27%) | called by pindel, varscan2*
- TRAV29DV5 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABAT | c.1116T>C p.P372= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- BEST1 | c.858C>T p.G286= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV57120116; called by muse, mutect2, varscan2
- CAT | c.288G>A p.K96= | Silent (SNP) | VAF 61/252 reads (24%) | catalogued as COSV53810565; called by muse, mutect2, varscan2
- DDR2 | c.1929G>T p.V643= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs182495290, COSV63369882; called by muse, mutect2, varscan2
- FAT2 | c.7678C>A p.R2560= | Silent (SNP) | VAF 78/166 reads (47%) | catalogued as COSV55815305; called by muse, mutect2, varscan2
- FGF3 | c.348G>A p.E116= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV61925420; called by muse, mutect2, varscan2
- GDF11 | c.1062G>A p.P354= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as rs77827308; called by muse, mutect2, varscan2
- HINT2 | c.435G>T p.V145= | Silent (SNP) | VAF 78/205 reads (38%) | catalogued as COSV52413502; called by muse, mutect2, varscan2
- HMCN1 | c.6615A>G p.Q2205= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs1046142909, COSV54884732; called by muse, mutect2, varscan2
- KMT5B | c.2400G>T p.V800= | Silent (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- KRT24 | c.237A>T p.G79= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV52879791; called by muse, mutect2
- MRPS18A | c.258T>G p.V86= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV64521894; called by muse, mutect2, varscan2
- MUC1 | c.3141C>G p.V1047= (on ENST00000611571 / NM_001371720.1; = p.V58= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV58111966; called by muse, mutect2, varscan2
- MUC17 | c.2289G>A p.E763= | Silent (SNP) | VAF 153/536 reads (29%) | catalogued as COSV60282717; called by muse, mutect2, varscan2
- PLEKHH2 | c.1674C>T p.A558= | Silent (SNP) | VAF 155/438 reads (35%) | catalogued as COSV56750776; called by muse, mutect2, varscan2
- POLD1 | c.1731C>A p.G577= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV70954495; called by muse, mutect2, varscan2
- RNF128 | c.393G>A p.K131= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV55249701; called by muse, mutect2, varscan2
- TCEA3 | c.273G>A p.E91= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs757097408, COSV65840827; called by muse, mutect2, varscan2
- TMEM161A | c.1182G>A p.T394= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV50776275; called by muse, mutect2, varscan2
- TRIM3 | c.795G>A p.P265= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs752144613, COSV61983338; called by muse, mutect2, varscan2
- TRPC5 | c.765G>C p.L255= | Silent (SNP) | VAF 70/98 reads (71%) | catalogued as COSV53286216; called by muse, mutect2, varscan2
- WASHC2A | c.3234C>T p.G1078= | Silent (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
